Somatic mutation profile of tumor specimen 0DTB93 from CCDI case PBCIXN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.6 years (2,428 days).
Specimen 0DTB93: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc77e58e-ceca-4434-9859-dfde321f3ee9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTB8G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99421d68-b7fb-43a0-a8e0-39469389de91

The open-access MAF lists 26 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 3, 5'Flank 3, 3'UTR 2, Silent 2, Nonsense Mutation 1, 5'UTR 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.787A>C p.T263P | Missense Mutation (SNP) | VAF 472/830 reads (57%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.236); catalogued as rs1057519829, COSV51768130; ClinVar: likely pathogenic; called by mutect2, varscan2
- DNAH7 | c.1762G>A p.D588N | Missense Mutation (SNP) | VAF 428/1024 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs759407761, COSV56753025, COSV56775553; called by muse, mutect2, varscan2
- ELMOD3 | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 390/5005 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV55706867; called by muse, mutect2
- FBP2 | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 35/753 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as rs1420187643, COSV100942191; called by muse, mutect2
- LCORL | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 440/1098 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0.247); catalogued as rs778244050, COSV100481573; called by muse, mutect2, varscan2
- TCF25 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 62/434 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs745908562, COSV54530634; called by muse, mutect2, varscan2
- TP53 | c.374del p.T125Sfs*45 | Frame Shift Del (DEL) | VAF 162/220 reads (74%) | catalogued as CM102351, CM157948, COSV52667346, COSV52673504, COSV52688693, COSV99037266; called by mutect2, varscan2
- TTN | c.86166G>T p.K28722N (on ENST00000591111; = p.K21298N on NM_003319.4) | Missense Mutation (SNP) | VAF 202/869 reads (23%) | PolyPhen probably damaging (0.997); catalogued as COSV60323926, COSV60339610; called by muse, mutect2, varscan2
- ARFGEF1 | c.3220C>T p.R1074* | Nonsense Mutation (SNP) | VAF 72/1418 reads (5%) | called by muse, mutect2
- CDH7 | c.626-1G>A p.X209_splice | Splice Site (SNP) | VAF 24/544 reads (4%) | called by muse, mutect2
- EVC | c.2700G>C p.Q900H | Missense Mutation (SNP) | VAF 30/578 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KRTAP4-3 | c.219C>G p.S73R | Missense Mutation (SNP) | VAF 114/803 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, varscan2
- OR2K2 | c.11C>A p.T4K | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2
- TBX22 | c.521C>G p.P174R | Missense Mutation (SNP) | VAF 80/328 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZSWIM6 | c.3621G>T p.M1207I | Missense Mutation (SNP) | VAF 213/1034 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- FCSK | c.2442G>T p.L814= | Silent (SNP) | VAF 199/486 reads (41%) | called by muse, mutect2, varscan2
- MOV10L1 | c.33C>T p.F11= | Silent (SNP) | VAF 40/770 reads (5%) | catalogued as rs754077120; called by muse, mutect2
- ACE | c.*88C>A | 3'UTR (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- ELMOD3 | c.943+216G>A | Intron (SNP) | VAF 245/3614 reads (7%) | catalogued as rs763868195; called by muse, mutect2
- HS3ST6 | c.*85G>A | 3'UTR (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- RPS6KL1 | c.-20-26C>A | Intron (SNP) | VAF 6/73 reads (8%) | catalogued as rs1436764463; called by muse, mutect2
- SIRPB2 | chr20:1491435 G>T | 5'Flank (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- SLC35B1 | chr17:49707962 G>T | 5'Flank (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- SOS2 | c.-87C>A | 5'UTR (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- TRPT1 | c.-9-41G>T | Intron (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- ZNF22 | chr10:45000746 G>A | 5'Flank (SNP) | VAF 44/814 reads (5%) | catalogued as rs753306135; called by muse, mutect2
